RC case RC-B56F — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/350d8849-4c82-4667-95cd-a74d1eb6c379

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (4)
1. Peripheral T-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 61.4 years (22,421 days); Year of diagnosis: 2014; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss / Night Sweats; Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph node, NOS / Lymph Node, Mediastinal / Lymph Node, Para-Aortic / Lymph Node, Retroperitoneal / Lymph Node, Supraclavicular.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 4.1 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOPE; Days to treatment start: 6 days; Days to treatment end: 85 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 119 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Initial disease status: Progressive Disease; Regimen or line of therapy: ICE; Days to treatment start: 604 days (1.7 years); Days to treatment end: 678 days (1.9 years); Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Other; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 717 days (2.0 years); Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 846 days (2.3 years); Days to treatment end: 958 days (2.6 years); Number of cycles: 8; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Duvelisib + Romidepsin; Initial disease status: Progressive Disease; Days to treatment start: 994 days (2.7 years); Days to treatment end: 1,106 days (3.0 years); Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Other; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Other; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 63.0 years (23,005 days); Days to diagnosis: 584 days (1.6 years).
3. Recurrence (histology not recorded by GDC). Age at diagnosis: 63.7 years (23,255 days); Days to diagnosis: 834 days (2.3 years).
4. Progression (histology not recorded by GDC). Age at diagnosis: 64.1 years (23,403 days); Days to diagnosis: 982 days (2.7 years).

Follow-up (9 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 60.
- Days to follow up: 62 days; Disease response: Tumor Free.
- Day 584 (recurrence): Progression or recurrence: Yes; Days to recurrence: 584 days (1.6 years).
- Days to follow up: 717 days (2.0 years); Disease response: Tumor Free.
- Day 834 (recurrence): Progression or recurrence: Yes; Days to recurrence: 834 days (2.3 years).
- Days to follow up: 924 days (2.5 years); Disease response: Partial Response.
- Day 982 (progression): Progression or recurrence: Yes; Days to progression: 982 days (2.7 years).
- Day 1,050 (end of treatment course 1): Disease response: Tumor Free.
- Days to follow up: 2,515 days (6.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 319 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Follow-up; Comorbidities: Abdominal Hernia.
- Timepoint category: Initial Diagnosis; Weight: 126.4 kg; Height: 168.5 cm; BMI: 44.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B56F-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B56F-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B56F-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 50; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
